Somatic mutation profile of tumor specimen TCGA-KL-8335-01A (aliquot TCGA-KL-8335-01A-11D-2310-10) from TCGA case TCGA-KL-8335, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 68.0 years (24,832 days).
Specimen TCGA-KL-8335-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca94105b-bb01-4eb8-8255-6f02426f4e2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8335-11A (Solid Tissue Normal), aliquot TCGA-KL-8335-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02fa1ab5-af62-4e1a-876f-dfa5c00e4c11

The open-access MAF lists 43 somatic variants for this specimen: 33 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 9, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 2, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.919+1G>A p.X307_splice | Splice Site (SNP) | VAF 36/48 reads (75%) | hotspot (GDC flag); catalogued as rs1131691039, CD920913, CS107068, CS120864, COSV52683145, COSV52775982, COSV52814989; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AK5 | c.281G>A p.R94Q (on ENST00000354567 / NM_174858.3; = p.R68Q on NM_012093.4) | Missense Mutation (SNP) | VAF 98/136 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs959882495, COSV100481391; called by muse, varscan2
- AKR1C4 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 23/240 reads (10%) | catalogued as rs782309814, CM151169, COSV99578573; called by muse, mutect2
- CALD1 | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100724102; called by muse, mutect2, varscan2
- CENPE | c.1201C>G p.L401V | Missense Mutation (SNP) | VAF 57/353 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs528315425, COSV99477364; called by muse, mutect2, varscan2
- COCH | c.1243C>G p.L415V (on ENST00000216361 / NM_001347720.1; = p.L350V on NM_004086.3) | Missense Mutation (SNP) | VAF 88/203 reads (43%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.976); catalogued as COSV99363473; called by muse, mutect2, varscan2
- CYP2F1 | c.882C>A p.N294K | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV100462605; called by muse, mutect2, varscan2
- DNM3 | c.209T>C p.V70A | Missense Mutation (SNP) | VAF 68/96 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100797897; called by muse, mutect2, varscan2
- ENAH | c.62A>T p.K21M | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99490300; called by muse, mutect2
- ERG | c.1316C>T p.A439V (on ENST00000398919 / NM_001243428.1; = p.A415V on NM_004449.4) | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV55734779; called by muse, mutect2, varscan2
- FAM184A | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 77/116 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs907958825, COSV58852042; called by muse, mutect2, varscan2
- FOLH1 | c.1738C>T p.R580* | Nonsense Mutation (SNP) | VAF 187/480 reads (39%) | catalogued as rs1199329267, COSV57047491; called by muse, mutect2, varscan2
- HCN4 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as rs761600737, COSV99983450; called by muse, mutect2, varscan2
- ICE1 | c.6766G>T p.E2256* | Nonsense Mutation (SNP) | VAF 52/111 reads (47%) | catalogued as COSV99664132; called by muse, mutect2, varscan2
- KDM2A | c.3370A>T p.I1124F | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV100445445; called by muse, mutect2, varscan2
- MPHOSPH10 | c.1278_1279insAGG p.E426_D427insR | In Frame Ins (INS) | VAF 18/27 reads (67%) | catalogued as COSV99732524; called by mutect2, pindel, varscan2
- NFKBIZ | c.1492G>T p.D498Y | Missense Mutation (SNP) | VAF 54/332 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58200931, COSV58200965; called by muse, mutect2, varscan2
- NLRP4 | c.2111C>T p.T704M | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as rs778909548, COSV100015860; called by muse, mutect2
- NPHS1 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs150180768; called by muse, mutect2, varscan2
- PLEKHB1 | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.563); catalogued as COSV99909468; called by muse, mutect2, varscan2
- RBM27 | c.161A>T p.D54V | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99505859; called by muse, mutect2, varscan2
- TSHZ3 | c.534G>T p.Q178H | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.387); catalogued as COSV99550992; called by muse, mutect2, varscan2
- TSPEAR | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as rs1425457705, COSV59957782, COSV59960387; called by muse, mutect2
- TTN | c.94232G>A p.R31411H (on ENST00000591111; = p.R23987H on NM_003319.4) | Missense Mutation (SNP) | VAF 9/135 reads (7%) | PolyPhen probably damaging (0.942); catalogued as rs72648276; called by muse, mutect2
- USF3 | c.4585C>G p.Q1529E | Missense Mutation (SNP) | VAF 61/322 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as COSV100324918, COSV100325661; called by muse, mutect2, varscan2
- ZFP37 | c.862G>T p.A288S | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV100953215; called by muse, mutect2
- ZFP82 | c.312G>A p.M104I | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV101088952; called by muse, mutect2
- ZNF365 | c.389C>A p.T130N | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.43); PolyPhen benign (0.107); catalogued as COSV101237949; called by muse, mutect2, varscan2
- ZNF462 | c.2851G>A p.V951M | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1366258936, COSV99471154; called by muse, mutect2, varscan2
- ZNF831 | c.1880C>T p.T627M | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753542321, COSV64038559; called by muse, mutect2, varscan2
- DIMT1 | c.30_49del p.R11Afs*29 | Frame Shift Del (DEL) | VAF 22/30 reads (73%) | called by mutect2, varscan2
- EPHA1 | c.1336+1del p.X446_splice | Splice Site (DEL) | VAF 19/64 reads (30%) | called by mutect2, pindel, varscan2
- PCGF1 | c.185_186del p.E62Vfs*17 | Frame Shift Del (DEL) | VAF 97/189 reads (51%) | called by pindel, varscan2
- GABRB3 | c.669T>A p.V223= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV100158938; called by muse, mutect2, varscan2
- INTS5 | c.141C>T p.G47= | Silent (SNP) | VAF 44/117 reads (38%) | catalogued as COSV100399529; called by muse, mutect2, varscan2
- OR9I1 | c.897C>T p.D299= | Silent (SNP) | VAF 53/131 reads (40%) | catalogued as rs758125970, COSV56925879; called by muse, mutect2, varscan2
- PCSK9 | c.133T>C p.L45= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV100135017; called by muse, varscan2
- PDE3A | c.294G>A p.A98= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs1240179857, COSV100761955; called by muse, mutect2, varscan2
- RETSAT | c.1092G>T p.L364= | Silent (SNP) | VAF 25/35 reads (71%) | catalogued as COSV99805932; called by muse, mutect2, varscan2
- SGSM3 | c.1038C>T p.D346= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as rs749911127, COSV50651675; called by muse, mutect2, varscan2
- ZNF260 | c.111C>T p.S37= | Silent (SNP) | VAF 70/168 reads (42%) | catalogued as rs1299831880, COSV101591038; called by muse, mutect2, varscan2
- ZNF462 | c.5448G>A p.E1816= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV99471157; called by muse, mutect2, varscan2
- RBFOX1 | c.28-185137G>A | Intron (SNP) | VAF 43/95 reads (45%) | catalogued as rs771567004, COSV60946776, COSV60951877; called by muse, mutect2, varscan2
